Surgical pathology report (de-identified scan), TCGA case TCGA-64-1681, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1681-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Right lung cancer.

Source of Specimen(s):

- 1: 10 R Lymph node
- 2: level 8 Lymph Node
- 3: 11R Lymph Node
- 4: bronchial Margin
- 5: 4R Lymph Node
- 6: 2R Lymph Node
- 7: level 7 Lymph Node
- 8: 10 R Lymph Node

Gross Description:

Received in eight parts.

Source of tissue: 1. Labeled #1, "10R lymph node"

Intraoperative Consultation: NO TUMOR SEEN.

Gross description: Received fresh labeled " patient name and medical number, 10R lymph node" consists of a 0.3 x 0.2 x 0.2 cm brown-black lymph node. The specimen is bisected and entirely frozen and submitted in cassette 1FS for microscopic evaluation.

Source of tissue: 2. Labeled #2, "level 8R lymph node"

Gross description: Received fresh labeled " patient name and medical number, level 8R lymph node" consists of a 1.5 x 0.4 x 0.2 cm brown-black lymph node. Entirely submitted in cassette 2A for microscopic evaluation.

Source of tissue: 3. Labeled #3, "11R lymph nodes"

Gross description: Received fresh labeled " patient name and medical number, 11R lymph node" consists of multiple brown-black lymph nodes 3 x 1 x 0.3 cm in aggregate. Entirely submitted in cassette 3A for microscopic evaluation.

Source of tissue: 4. Labeled #4, "bronchial margin"

Intraoperative Consultation: BRONCHIAL MARGIN; NO TUMOR SEEN.

Gross description: Received fresh for frozen section diagnosis labeled " patient name and medical number, bronchial margin" consists of a 125 gram,

[page 2 of 3]
13 x 10 x 3 cm lobe of lung. The pleura is tan-red with a 2.2 cm firm, rubbery indurated area that lies approximately 2.5 cm from the bronchial margin. The indurated area is inked blue and the staple lines are inked black, and the specimen is sectioned revealing a 2.5 x 2.2 x 2 cm tan-gray, rubbery tumor mass that comes within 0.6 cm of the bronchial margin and that abuts the pleural surface corresponding to blue inked area. The remainder of the parenchyma is red-tan and spongy to mildly congested. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 4FS bronchial margin. 4A vessel margins. 4B lymph nodes. 4C staple margin. 4D tumor in relation to bronchial margin. 4E-4F tumor in relation to pleural surface. 4G tumor in relation to normal. 4H normal.

Source of tissue: 5. Labeled #5, "4R lymph nodes"

Gross description: Received fresh labeled " patient name and medical number, 4R lymph nodes" consists of a 2.5 x 1.5 x 0.4 cm aggregate of yellow lobulated fat and brown-black lymph nodes. Entirely submitted in cassettes 5A-5B for microscopic evaluation.

Source of tissue: 6. Labeled #6, "2R lymph nodes"

Gross description: Received fresh labeled " patient name and medical number, 2R lymph nodes" consists of a 2 x 0.4 x 0.4 cm brown lymph node. The specimen is bisected and entirely submitted in cassette 6A for microscopic evaluation.

Source of tissue: 7. Labeled #7, "level 7 lymph nodes"

Gross description: Received fresh labeled " patient name and medical number, level 7 lymph nodes" consists of multiple brown-black lymph nodes 2.5 x 1 x 0.3 cm. Entirely submitted in cassette 7A for microscopic evaluation.

Source of tissue: 8. Labeled #8, "10R lymph nodes"

Gross description: Received fresh labeled " patient name and medical number, 10R lymph nodes" consists of two black lymph nodes 0.5 x 0.3 x 0.2 cm and 0.9 x 0.5 x 0.3 cm. Entirely submitted in cassette 8A for microscopic evaluation.

Final Diagnosis:

1. 10R lymph node:

- No tumor seen in one lymph node (0/1).

[page 3 of 3]
2. Level 8R lymph node:

- No tumor seen in seven lymph nodes (0/7).

3. 11R lymph nodes:

- No tumor seen in five lymph nodes (0/5).

4. Right lung, unspecified lobectomy:

- Adenocarcinoma (2.5 cm), well-differentiated.
- Visceral pleura free of tumor.
- Angiolymphatic invasion is not identified.
- Bronchial and vascular margins free of tumor.
- No tumor seen in four lymph nodes (0/4).

5. 4R lymph nodes:

- No tumor seen in thirteen lymph nodes (0/13).

6. 2R lymph nodes:

- No tumor seen in six lymph nodes (0/6).

7. Level 7 lymph nodes:

- No tumor seen in eight lymph nodes (0/8).

8. 10R lymph nodes:

- No tumor seen in two lymph nodes (0/2).

- pT1 N0 Mx

Source: NCI Genomic Data Commons file 4e4b0c4c-57a5-4e8b-8db6-698ddea2bdee (TCGA-64-1681.DE31291A-CED6-458B-8FB7-AD47AE581B64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).